Somatic mutation profile of tumor specimen MP2PRT-PATHZM-TMP1-A (aliquot MP2PRT-PATHZM-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATHZM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,598 days).
Specimen MP2PRT-PATHZM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86d2e580-95e9-45f1-9e2f-d5363227c921.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHZM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHZM-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b20657e0-cf3c-4028-913d-25557f804e44

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 3, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER3 | c.2138G>T p.G713V | Missense Mutation (SNP) | VAF 159/482 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs375343329; called by muse, mutect2, varscan2
- METTL3 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 12/276 reads (4%) | catalogued as COSV52970552; called by muse, mutect2
- RASEF | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 68/738 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.535); catalogued as COSV61551050; called by muse, mutect2
- SLC25A43 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs780293558; called by muse, mutect2
- SRRM2 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 133/395 reads (34%) | catalogued as COSV100070857; called by muse, mutect2, varscan2
- FNBP1L | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV3-30 | chr14:106335080 del TCTTTC | Missense Mutation (DEL) | VAF 31/307 reads (10%) | called by pindel*, varscan2
- LEXM | c.753C>A p.Y251* | Nonsense Mutation (SNP) | VAF 102/266 reads (38%) | called by muse, mutect2, varscan2
- PHF2 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- POLR2L | c.4A>T p.I2F | Missense Mutation (SNP) | VAF 99/356 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- RNPEPL1 | c.608G>C p.R203P | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VPREB1 | c.151_154del p.V51Tfs*18 | Frame Shift Del (DEL) | VAF 98/355 reads (28%) | called by pindel, varscan2
- CCDC80 | c.666G>A p.L222= | Silent (SNP) | VAF 167/501 reads (33%) | called by muse, mutect2, varscan2
- CFAP57 | c.2790C>T p.V930= | Silent (SNP) | VAF 14/461 reads (3%) | called by muse, mutect2
- CUBN | c.1317C>T p.N439= | Silent (SNP) | VAF 175/419 reads (42%) | catalogued as rs1352086308; called by muse, mutect2, varscan2
- CDH13 | c.484-45819A>G | Intron (SNP) | VAF 90/288 reads (31%) | called by muse, mutect2, varscan2
